Somatic mutation profile of tumor specimen 0DRVOQ from CCDI case PBCGSK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 12.9 years (4,701 days).
Specimen 0DRVOQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 940d1903-9404-4cdd-8d38-b749ee346e25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRVOZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e08177c-0ad3-43cb-a614-94a3bc5c5788

The open-access MAF lists 31 somatic variants for this specimen: 15 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 11, Intron 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 109/386 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- ATF6B | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV64351881; called by muse, mutect2
- FAM149B1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 175/1396 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs563864481, COSV54355106; called by muse, mutect2, varscan2
- GIN1 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 294/929 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV67536098; called by muse, mutect2, varscan2
- LAMA1 | c.6220G>A p.V2074M | Missense Mutation (SNP) | VAF 251/860 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs758250392, COSV67544899; called by muse, mutect2, varscan2
- PARD3B | c.3304C>T p.R1102W (on ENST00000406610 / NM_001302769.2; = p.R1033W on NM_057177.7) | Missense Mutation (SNP) | VAF 42/766 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs369194609; called by muse, mutect2
- PCDHA2 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs574219981; called by muse, mutect2
- RAF1 | c.779C>G p.T260R | Missense Mutation (SNP) | VAF 275/914 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as CM073288, CM073290, COSV52574554, COSV52575813; called by muse, varscan2
- SF3B1 | c.2027G>T p.G676V | Missense Mutation (SNP) | VAF 102/1214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59215389; called by muse, mutect2
- SKI | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs863223722; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- SLC12A2 | c.2885T>C p.L962S | Missense Mutation (SNP) | VAF 112/1212 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99321475; called by muse, mutect2
- EYS | c.2859T>A p.N953K | Missense Mutation (SNP) | VAF 250/712 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MFAP3L | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 38/870 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- XYLT1 | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 191/644 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ZBTB34 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATP6V1H | c.978C>T p.Y326= | Silent (SNP) | VAF 275/1154 reads (24%) | catalogued as rs1277535195; called by muse, mutect2, varscan2
- COCH | c.1395G>A p.S465= (on ENST00000216361 / NM_001347720.1; = p.S400= on NM_004086.3) | Silent (SNP) | VAF 53/929 reads (6%) | catalogued as rs150529026, COSV53552459; called by muse, mutect2
- COL4A6 | c.3234C>T p.S1078= | Silent (SNP) | VAF 207/294 reads (70%) | catalogued as rs1193994315, COSV57868267; called by muse, mutect2, varscan2
- EDRF1 | c.2718G>A p.T906= (on ENST00000356792 / NM_001202438.2; = p.T872= on NM_015608.2) | Silent (SNP) | VAF 266/684 reads (39%) | catalogued as rs199534470, COSV100523256, COSV61762892; called by mutect2, varscan2
- INSM2 | c.1131G>A p.Q377= | Silent (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- MTLN | c.69C>T p.V23= | Silent (SNP) | VAF 204/940 reads (22%) | called by muse, mutect2, varscan2
- NEFH | c.615C>T p.F205= | Silent (SNP) | VAF 66/258 reads (26%) | catalogued as rs1301849129; called by muse, mutect2, varscan2
- OSBP2 | c.1014C>T p.D338= | Silent (SNP) | VAF 47/291 reads (16%) | catalogued as rs149092338, COSV60243466; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 48/1243 reads (4%) | called by muse, mutect2
- SYN3 | c.1518C>T p.L506= | Silent (SNP) | VAF 131/673 reads (19%) | catalogued as rs776753346; called by muse, mutect2, varscan2
- ZSCAN22 | c.747T>C p.D249= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs1216094324, COSV100308551; called by muse, mutect2, varscan2
- COL20A1 | c.2806+28C>A | Intron (SNP) | VAF 129/425 reads (30%) | called by muse, mutect2, varscan2
- GLP1R | c.*72C>T | 3'UTR (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- ITGA5 | c.2842-61del | Intron (DEL) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- NIPBL | c.8049+76C>T | Intron (SNP) | VAF 21/235 reads (9%) | called by muse, mutect2
- SH3TC2 | c.3204+13C>A | Intron (SNP) | VAF 141/554 reads (25%) | called by muse, mutect2, varscan2
